Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7383, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7383-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

1) TONSIL, RIGHT, TONSILLECTOMY: MODERATELY-DIFFERENTIATED SQUAMOUS CELL CARCINOMA; MARGINS NEGATIVE FOR MALIGNANCY.

2) LYMPH NODES, RIGHT NECK LEVELS 2 AND 3, DISSECTION: 19 LYMPH NODES, NEGATIVE FOR MALIGNANCY.

3) LYMPH NODES, RIGHT PERIFACIAL, DISSECTION: 2 LYMPH NODES, NEGATIVE FOR MALIGNANCY.

**Electronically Signed Out by [REDACTED]

CLINICAL DATA

Clinical Features: Unspecified

Operator: [REDACTED]

Operation: Radical tonsil resection; cervical lymphadenopathy

Operative Findings: Unspecified

Operative Diagnosis: Right tonsillar pillar lesion

Tissue Submitted: 1) right tonsil, 2) levels 2 and 3 (single long stitch-level 2, double long stitch-level 3), 3) right perifacial lymph nodes

GROSS DESCRIPTION:

1) SOURCE: Right Tonsil

Received fresh labeled, "right tonsil," is a single fragment of shiny pink-tan tissue, grossly consistent with a palatine tonsil, and measuring 3.2 x 1.7 x 1.1 cm. The mucosal surface is pink-tan and shiny with a defect present in the center of the specimen that measures 1.2 cm. Part of this defect appears surgical. The soft tissue surface demonstrates extensive cautery. The cauterized surface is inked in black. The specimen is serially sectioned to reveal irregular tan-pink parenchyma. The specimen is entirely submitted.

Summary of sections: 1A, 3/1; 1B-C, 2/1 each.

2) SOURCE: Right Neck Dissection, Level 2 & 3

[REDACTED]

[page 2 of 2]
Received fresh labeled, "right neck dissection," are multiple fragments of fibrofatty tissue, measuring in aggregate 8.2 x 4.7 x 1.5 cm. There is a single long stitch present on one aspect of the specimen. The stitch is not adequately oriented and no second stitch is present. A thorough lymph node search is performed and 18 potential lymph nodes are identified. Lymph nodes are submitted from the side opposite the stitch to the side closest to the stitch.

Summary of sections: 2A, 8/1; 2B, 7/1; 2C, 3/1.

3) SOURCE: Right Perifacial Lymph Nodes

Received fresh labeled, "right perifacial lymph nodes," are two fragments of fibrofatty tissue, measuring in aggregate 2.0 x 2.3 x 0.7 cm. The specimen is entirely submitted.

Summary of sections: 3A, 2/1.

Dictated by

[REDACTED]

Slides and report reviewed by Attending Pathologist.

Source: NCI Genomic Data Commons file b2153793-b55e-4693-9a78-f509a2a0e76f (TCGA-CR-7383.B5C09242-0E76-49E7-9A35-17CA560D7A7B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).